Gene-level copy-number profile of tumor specimen TCGA-E1-A7Z2-01A from TCGA case TCGA-E1-A7Z2, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 58.4 years (21,341 days).
Specimen TCGA-E1-A7Z2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.70047fe6-c4a9-4351-a78a-d928e0e68ef3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E1-A7Z2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/17b980a8-d3df-40cf-a597-9f72d9a4eb0d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 94; copy number 1: 8,720; copy number 2: 47,844; copy number 3: 2,076; copy number 4: 1,077.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E1-A7Z2-01A-21D-A34I-01): tumor purity 0.74, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 94 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:144,434,826–146,050,366, 12 genes: PPIAP83, RNU6ATAC40P, TPK1, EEF1A1P10, RN7SKP174, EI24P4, AC073310.1, RPL7P59, AC004911.1, DPY19L4P2, AC006007.1, AC073308.1.
- chr7:147,671,711–148,446,299, 8 genes: AC005518.1, AC005518.2, RNU6-1184P, RNA5SP249, RN7SL456P, U3, RN7SL72P, AC083849.1.
- chr9:10,532,145–11,276,314, 8 genes: AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1.
- chr9:11,618,530–12,058,227, 1 gene (within-gene range 0–1): AL353595.1.
- chr9:12,685,439–12,710,285, 1 gene: TYRP1.
- chr9:12,885,321–13,279,692, 5 genes (within-gene range 0–1): Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ.
- chr9:14,921,013–15,307,360, 6 genes (within-gene range 0–1): CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B.
- chr9:19,507,452–20,622,499, 11 genes (within-gene range 0–1): SLC24A2, C11orf98P1, AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3, AL512635.1, MLLT3, MIR4473, RNU4-26P.
- chr9:21,135,598–21,699,596, 36 genes: AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P.
- chr9:21,994,139–22,214,672, 6 genes: CDKN2B-AS1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,554. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
